FM case AD14713 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/46162a3b-f8ac-4fb5-a895-d1ec1905e385

Female, 50.5 years: Thymoma, NOS (ICD-O-3 8580/1) of the thymus; metastasis. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
